Gene-level copy-number profile of tumor specimen TCGA-AP-A05H-01A from TCGA case TCGA-AP-A05H, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 76.0 years (27,744 days).
Specimen TCGA-AP-A05H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.66e3afd8-4b5c-41a2-a714-5b10444aaae7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AP-A05H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2a781008-5137-4f33-8a85-69884cf61989

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,653; copy number 2: 26,939; copy number 3: 22,473; copy number 4: 6,558; copy number 5: 1,268; copy number 6: 654; copy number 7: 45; copy number 8: 23; copy number 9: 128; copy number 10: 70.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AP-A05H-01A-11D-A00X-01): tumor purity 0.9, ploidy 2.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,188 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:93,179,919–93,278,730, 1 gene, copy number 5 (within-gene range 3–5): CCDC18.
- chr1:93,199,755–94,275,068, 27 genes, copy number 5 (within-gene range 3–5): AC126124.1, CCDC18-AS1, AL139421.1, DR1, AL137159.1, Y_RNA, FNBP1L, RNA5SP53, BCAR3, BCAR3-AS1, MIR760, AL049796.1, DNTTIP2, GCLM, CHCHD2P5, MTND4P11, MTND3P21, MTCO3P21, MTATP6P13, AL117351.2, MTCO2P21, MTCO1P21, AL117351.1, ABCA4, AC093579.1, ARHGAP29, RN7SL440P.
- chr1:143,343,180–157,191,963, 646 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:172,210,711–172,468,831, 4 genes, copy number 5 (within-gene range 3–5): AL137157.1, RNU6-157P, PIGC, C1orf105.
- chr1:177,351,562–177,920,152, 3 genes, copy number 6 (within-gene range 3–6): LINC01645, AL136114.1, LINC01741.
- chr2:15,564,170–15,744,339, 4 genes, copy number 5: AC008278.2, DDX1, AC008278.1, LINC01804.
- chr2:68,023,694–68,117,200, 3 genes, copy number 5: FBXL12P1, C1D, AC017083.4.
- chr2:68,125,265–68,125,747, 1 gene, copy number 5: PPIAP64.
- chr2:69,396,113–71,130,239, 59 genes, copy number 5: NFU1, AAK1, RN7SL604P, SNORA36C, RPL36AP16, B3GALNT1P1, ANXA4, AC092431.1, GMCL1, AC019206.1, RPL23AP92, SNRNP27, MXD1, ASPRV1, PCBP1-AS1, RN7SL470P, PCBP1, AC016700.1, MRPL36P1, LINC01816, C2orf42, TIA1, MIR1285-2, RPL39P15, PCYOX1, SNRPG, FAM136A, AC022201.2, BRD7P6, AC022201.1, TGFA, TGFA-IT1, ADD2, AC005234.2, AC005234.1, FIGLA, HMGN2P21, CLEC4F, MOB4P1, CD207, LINC01143, AC007040.3, VAX2, ATP6V1B1, AC007040.2, ATP6V1B1-AS1, ELOCP21, RN7SL160P, ANKRD53, TEX261, AC007040.1, AC007881.2, OR7E91P, OR7E46P, OR7E62P, NAGK, AC007881.3, MCEE, AC007881.4.
- chr2:113,067,970–113,756,693, 30 genes, copy number 7 (within-gene range 3–7): IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782.
- chr2:151,802,651–152,649,826, 11 genes, copy number 6 (within-gene range 3–6): AC068547.1, CACNB4, AC079790.1, STAM2, RPL30P2, AC079790.2, Y_RNA, FMNL2, NUDCP1, AC012066.1, AC012443.1.
- chr2:159,186,835–159,286,703, 2 genes, copy number 5: MIR6888, WDSUB1.
- chr2:159,386,367–159,404,636, 1 gene, copy number 5: AC008277.1.
- chr3:13,816,258–14,574,792, 19 genes, copy number 5: WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124, SLC6A6, GRIP2, RNU6-905P, RHBDF1P1.
- chr3:39,025,987–39,397,351, 22 genes, copy number 5: RNU6-1227P, WDR48, GORASP1, TTC21A, MIR6822, CSRNP1, AC092053.3, AC092053.2, Metazoa_SRP, AC092053.4, XIRP1, AC092053.6, DSTNP4, AC092053.5, CX3CR1, AC092053.1, AC104850.2, CCR8, HNRNPA1P21, AC104850.1, EEF1A1P24, SLC25A38.
- chr3:99,638,475–100,993,515, 21 genes, copy number 5 (within-gene range 3–5): COL8A1, AC069222.1, CMSS1, FILIP1L, MIR3921, AC129803.1, TMEM30CP, DUSP12P1, VTI1BP1, TBC1D23, NIT2, TOMM70, LNP1, TMEM45A, ADGRG7, AC069223.1, GMFBP1, TFG, ABI3BP, AC080014.1, RNU6-865P.
- chr3:188,562,238–189,897,276, 9 genes, copy number 5 (within-gene range 4–5): LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944.
- chr5:30,733,557–32,110,932, 27 genes, copy number 5 (within-gene range 4–5): AC026433.1, RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279.
- chr6:47,231,532–47,477,572, 4 genes, copy number 5 (within-gene range 3–5): TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1.
- chr6:75,291,859–76,092,940, 22 genes, copy number 6 (within-gene range 3–6): FILIP1, HMGB1P39, AL445465.1, U3, MIR4463, AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20, H3P27, RNU6-1338P, SENP6, AL356057.1, RNU6-1016P, RN7SKP163, AL109897.1, MYO6, RNU6-155P, RNA5SP209, IMPG1, Y_RNA, RNU6-248P.
- chr6:80,003,887–80,084,776, 4 genes, copy number 5: TTK, AL591135.2, AL591135.1, AK4P5.
- chr6:125,119,049–125,302,078, 3 genes, copy number 5: TPD52L1, HDDC2, AL121938.1.
- chr6:131,470,832–133,150,816, 52 genes, copy number 5 (within-gene range 3–5): ARG1, MED23, ENPP3, RNU4-18P, OR2A4, CTAGE9, AC005587.1, MIR548H5, ENPP1, SELENOKP2, RN7SKP245, AL139805.1, AL117378.1, AL117378.2, CCN2, AL133346.1, AL021408.1, MIR548AJ1, AL021408.2, LINC01013, EEF1A1P36, MOXD1, STX7, RPL21P66, TAAR9, TAAR8, TAAR7P, TAAR6, TAAR5, TAAR4P, AL513524.1, TAAR3P, TAAR2, TAAR1, HLFP1, VNN1, CCNG1P1, VNN3, VNN2, AL032821.1, RBM11P1, SLC18B1, RPS12, SNORD101, SNORD100, SNORA33, HMGB1P13, AL137783.1, LINC00326, RPL23AP46, AL591115.1, MTCYBP4.
- chr6:158,515,605–159,000,202, 16 genes, copy number 5: CACYBPP3, TMEM181, TATDN2P2, MIR7161, DYNLT1, SYTL3, AMZ2P2, MIR3918, EZR, EZR-AS1, OSTCP1, AL627422.2, C6orf99, AL627422.1, RNU6-293P, RSPH3.
- chr6:163,163,830–163,346,744, 3 genes, copy number 5 (within-gene range 3–5): PACRG-AS3, PACRG-AS1, AL031121.2.
- chr8:39,584,489–40,172,612, 14 genes, copy number 6 (within-gene range 3–6): ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1.
- chr8:100,427,559–101,169,629, 25 genes, copy number 6: AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1.
- chr8:124,192,671–125,541,373, 30 genes, copy number 6 (within-gene range 4–6): AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1.
- chr8:138,130,023–144,361,286, 167 genes, copy number 6 (broad region; genes not listed).
- chr10:35,604,485–36,524,234, 14 genes, copy number 6–7: AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1.
- chr10:94,278,681–94,855,547, 11 genes, copy number 5: PLCE1-AS1, AL139124.1, NOC3L, TBC1D12, HELLS, AL138759.1, CTBP2P2, CYP2C18, AL583836.1, CYP2C19, MTND4P19.
- chr11:45,486,867–47,378,547, 64 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:50,504,985–56,144,674, 298 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr12:56,663,341–57,626,151, 53 genes, copy number 6–8 (within-gene range 2–8): PTGES3, RN7SL809P, NACA, AC117378.1, PRIM1, HSD17B6, AC121758.2, AC121758.4, AC121758.3, AC121758.1, SDR9C7, AC026120.2, RDH16, AC026120.1, AC026120.3, GPR182, ZBTB39, TAC3, MYO1A, NEMP1, NAB2, STAT6, LRP1, LRP1-AS, MIR1228, NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10.
- chr17:8,802,722–9,244,000, 6 genes, copy number 7 (within-gene range 3–7): PIK3R6, PIK3R5, AC002091.2, AC002091.1, NTN1, AC005695.1.
- chr17:39,461,486–40,061,215, 29 genes, copy number 9 (within-gene range 4–9): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124.
- chr19:6,661,253–11,619,161, 265 genes, copy number 6 (broad region; genes not listed).
- chr20:31,421,436–33,443,763, 78 genes, copy number 6–9 (broad region; genes not listed).
- chr20:61,953,469–62,065,810, 1 gene, copy number 5 (within-gene range 3–5): TAF4.
- chr20:62,037,429–64,313,132, 136 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,653. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
